Somatic mutation profile of tumor specimen TARGET-40-NAAGJT-01A (aliquot TARGET-40-NAAGJT-01A-01D) from TARGET case TARGET-40-NAAGJT, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 21.3 years (7,763 days).
Specimen TARGET-40-NAAGJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e66b17e8-80d6-4e23-bc5f-6463c63e0f88.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJT-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJT-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e97f8f-1cb2-4ae4-9b93-9b82dac0f5b6

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.20750T>C p.M6917T | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as rs1404825309, COSV101200377; called by muse, mutect2, varscan2
- PCLO | c.5266C>T p.R1756C | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1415697327, COSV61623247; called by muse, mutect2, varscan2
- CNTNAP2 | c.3978A>C p.K1326N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH14 | c.6157A>T p.K2053* (on ENST00000445597; = p.K2706* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 35/224 reads (16%) | called by muse, mutect2
- FOXC1 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by mutect2, varscan2
- TTN | c.50515C>A p.P16839T (on ENST00000591111; = p.P9415T on NM_003319.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA13 | c.11967T>A p.A3989= | Silent (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.15687T>G p.S5229= | Silent (SNP) | VAF 40/282 reads (14%) | called by muse, mutect2, varscan2
